TARGET case TARGET-30-PAMLCS — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/93f4e7ca-e314-5bda-b1c5-9fda44236f6b

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 4.5 years (1,643 days); Year of diagnosis: 2003; Days to last follow up: 87 days; INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PAMLCS-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
